Somatic mutation profile of tumor specimen 0DMN2E from CCDI case PBCAUJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Spinal cord; Age at diagnosis: 8.0 years (2,926 days).
Specimen 0DMN2E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 913efec8-d52f-43ab-ae1d-00f88025ff1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMN1G (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e65942ac-65b4-412c-bf19-25d5947a8b89

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCB1 | c.351dup p.T118Hfs*6 (on ENST00000263121; = p.T118Hfs*52 on NM_003073.5) | Frame Shift Ins (INS) | VAF 254/729 reads (35%) | catalogued as rs1555876140; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ALDOC | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 80/1032 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as rs1164570899, COSV52025304, COSV52027342; called by muse, mutect2
- H3C4 | c.360C>G p.I120M | Missense Mutation (SNP) | VAF 73/811 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV61911606; called by muse, mutect2
- SIGLEC9 | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 289/736 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs140509430; called by muse, mutect2, varscan2
- SYT14 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 371/995 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.922); catalogued as COSV55050622; called by muse, mutect2, varscan2
- TANGO2 | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 120/1172 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.189); catalogued as rs199621230, COSV59295143; ClinVar: uncertain significance; called by muse, mutect2
- TTLL3 | c.1801G>A p.V601M | Missense Mutation (SNP) | VAF 406/963 reads (42%) | SIFT tolerated (0.64); PolyPhen benign (0.073); catalogued as rs771480120, COSV59613675; called by muse, mutect2, varscan2
- CDHR5 | c.660C>T p.T220= | Silent (SNP) | VAF 278/737 reads (38%) | catalogued as rs778453058, COSV62764261; called by muse, mutect2, varscan2
- MMP16 | c.171C>T p.D57= | Silent (SNP) | VAF 30/632 reads (5%) | catalogued as rs1476934120; called by muse, mutect2
- MTA1 | c.813G>A p.A271= | Silent (SNP) | VAF 48/800 reads (6%) | catalogued as rs1555430882; called by muse, mutect2
- SMARCB1 | c.363-2242C>T | Intron (SNP) | VAF 347/805 reads (43%) | catalogued as CM991144, COSV54093065; called by muse, mutect2, varscan2
